Somatic mutation profile of cancer-model specimen HCM-BROD-0204-C25-85A (3D Organoid, passage 8; aliquot HCM-BROD-0204-C25-85A-01D-A79L-36), derived from the primary tumor of HCMI case HCM-BROD-0204-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: GX; Age at diagnosis: 74.5 years (27,193 days).
Specimen HCM-BROD-0204-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b02747b9-6f5c-477c-9682-794f83484c93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0204-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0204-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92bd12bb-4ff1-44ea-b16c-a3eab64adcd8

The open-access MAF lists 71 somatic variants for this specimen: 55 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 15, Frame Shift Del 10, Nonsense Mutation 3, In Frame Del 2, Frame Shift Ins 2, Splice Region 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 146/325 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACVR2A | c.1409T>G p.L470* | Nonsense Mutation (SNP) | VAF 173/391 reads (44%) | catalogued as COSV54027320; called by muse, mutect2, varscan2
- ANO2 | c.1003C>T p.R335C (on ENST00000356134 / NM_001278597.3; = p.R339C on NM_001278596.3) | Missense Mutation (SNP) | VAF 172/356 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs372991029, COSV59050232; called by muse, mutect2, varscan2
- CALD1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 189/610 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775853439, COSV62647217; called by muse, mutect2, varscan2
- CDH11 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 227/444 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1442976496; called by muse, mutect2, varscan2
- COL9A2 | c.1826T>A p.V609E | Missense Mutation (SNP) | VAF 67/591 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.028); catalogued as COSV65622102; called by muse, mutect2, varscan2
- COMMD8 | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 83/164 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1040980400; called by muse, mutect2, varscan2
- ERICH6 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747343551, COSV55799129, COSV55801704; called by muse, mutect2, varscan2
- KDM6A | c.1838del p.N613Tfs*12 | Frame Shift Del (DEL) | VAF 275/383 reads (72%) | catalogued as COSV100938111; called by mutect2, pindel, varscan2
- LRRC7 | c.3586G>A p.V1196I (on ENST00000651989 / NM_001370785.2; = p.V1163I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 192/367 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.108); catalogued as rs921438582, COSV50476832; called by muse, mutect2, varscan2
- MARCO | c.612G>A p.A204= | Splice Region (SNP) | VAF 191/459 reads (42%) | catalogued as rs374483780; called by muse, mutect2, varscan2
- MYO18B | c.6773G>A p.R2258Q | Missense Mutation (SNP) | VAF 299/576 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs551701390, COSV59135064; called by muse, mutect2, varscan2
- NAALAD2 | c.1144del p.V382Lfs*14 | Frame Shift Del (DEL) | VAF 161/401 reads (40%) | catalogued as rs762564730; called by mutect2, pindel, varscan2
- PCDHA3 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 494/983 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs781845951, COSV63542188; called by muse, mutect2, varscan2
- PCDHGA6 | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 420/958 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV53960452; called by muse, varscan2
- PLXND1 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 288/530 reads (54%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs373023998; called by muse, mutect2, varscan2
- RAI1 | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 343/343 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866732668; called by muse, mutect2, varscan2
- ROR2 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 334/660 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.663); catalogued as rs778107703, COSV100995795; called by muse, varscan2
- SCAF4 | c.1068G>A p.Q356= | Splice Region (SNP) | VAF 119/208 reads (57%) | catalogued as COSV54593371; called by muse, mutect2, varscan2
- SEZ6 | c.2870T>C p.L957P | Missense Mutation (SNP) | VAF 109/138 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1174199087; called by muse, mutect2, varscan2
- SH2D5 | c.1004G>A p.R335H (on ENST00000444387 / NM_001103161.2; = p.R251H on NM_001103160.2) | Missense Mutation (SNP) | VAF 754/754 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs200472543; called by muse, mutect2, varscan2
- SLC1A5 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 252/524 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs1265553548; called by muse, mutect2, varscan2
- SLC9A8 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 275/505 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.719); catalogued as rs144315631; called by muse, mutect2, varscan2
- SPTB | c.2116C>T p.R706C | Missense Mutation (SNP) | VAF 337/662 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs184962510; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 322/612 reads (53%) | PolyPhen probably damaging (0.993); catalogued as rs755409104, COSV59570371; called by muse, mutect2, varscan2
- TBL1X | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 239/239 reads (100%) | PolyPhen benign (0.003); catalogued as COSV54280566; called by muse, mutect2, varscan2
- ABCG5 | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 186/381 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADD2 | c.775_796del p.Y259Sfs*22 | Frame Shift Del (DEL) | VAF 193/500 reads (39%) | called by mutect2, pindel, varscan2
- ALX1 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 229/510 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF5 | c.111del p.E39Kfs*26 | Frame Shift Del (DEL) | VAF 91/614 reads (15%) | called by mutect2, varscan2
- ARID1A | c.3429del p.Q1145Rfs*16 | Frame Shift Del (DEL) | VAF 393/544 reads (72%) | called by mutect2, pindel, varscan2
- CBLN3 | c.541C>A p.L181M | Missense Mutation (SNP) | VAF 28/634 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSK | c.438T>G p.F146L | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP2U1 | c.922T>A p.S308T | Missense Mutation (SNP) | VAF 175/360 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCTN2 | c.253G>C p.E85Q (on ENST00000548249 / NM_001261413.2; = p.E90Q on NM_006400.4) | Missense Mutation (SNP) | VAF 166/377 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, varscan2
- DVL1 | c.1971_2010del p.P658Rfs*3 (on ENST00000378888 / NM_001330311.2; = p.P633Rfs*3 on NM_004421.3) | Frame Shift Del (DEL) | VAF 535/655 reads (82%) | called by mutect2, pindel, varscan2
- ERBB4 | c.1521_1531del p.C507Wfs*18 | Frame Shift Del (DEL) | VAF 127/304 reads (42%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.2191C>A p.P731T | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- JAKMIP1 | c.1724T>C p.M575T | Missense Mutation (SNP) | VAF 152/322 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAN2A1 | c.140_165del p.Q47Rfs*9 | Frame Shift Del (DEL) | VAF 78/225 reads (35%) | called by mutect2, pindel, varscan2
- NAE1 | c.452dup p.L151Ffs*4 | Frame Shift Ins (INS) | VAF 143/347 reads (41%) | called by mutect2, pindel, varscan2
- OR14A16 | c.455dup p.I153Dfs*26 | Frame Shift Ins (INS) | VAF 132/279 reads (47%) | called by mutect2, pindel, varscan2
- OR7A5 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 220/430 reads (51%) | called by muse, mutect2, varscan2
- PCLO | c.3894_3909del p.L1298Ffs*15 | Frame Shift Del (DEL) | VAF 217/760 reads (29%) | called by mutect2, pindel, varscan2
- PDZRN3 | c.1706G>T p.S569I | Missense Mutation (SNP) | VAF 299/586 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- POM121L2 | c.1540A>G p.S514G | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POTEG | c.396G>T p.R132S | Missense Mutation (SNP) | VAF 291/2186 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POU6F2 | c.1950_1958del p.V651_V653del | In Frame Del (DEL) | VAF 236/667 reads (35%) | called by mutect2, pindel, varscan2
- PPP1R9B | c.613T>A p.S205T | Missense Mutation (SNP) | VAF 412/421 reads (98%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- RPL11 | c.289_291del p.N97del (on ENST00000374550 / NM_001199802.1; = p.N98del on NM_000975.5) | In Frame Del (DEL) | VAF 249/261 reads (95%) | called by pindel, varscan2
- SCAF4 | c.1068+1G>A p.X356_splice | Splice Site (SNP) | VAF 118/206 reads (57%) | called by muse, mutect2, varscan2
- SRRM4 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 247/481 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TG | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 242/490 reads (49%) | called by muse, mutect2, varscan2
- TNFRSF21 | c.1344del p.S449Pfs*30 | Frame Shift Del (DEL) | VAF 265/369 reads (72%) | called by mutect2, pindel, varscan2
- ZSCAN5B | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 200/419 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM19 | c.2340G>A p.P780= | Silent (SNP) | VAF 185/371 reads (50%) | catalogued as rs745765474; called by muse, mutect2, varscan2
- ALPL | c.525C>T p.S175= | Silent (SNP) | VAF 258/552 reads (47%) | catalogued as rs766504809; called by muse, mutect2, varscan2
- APOBEC3D | c.297G>A p.Q99= | Silent (SNP) | VAF 243/519 reads (47%) | catalogued as rs1354790664; called by muse, mutect2, varscan2
- CASS4 | c.2097C>T p.P699= | Silent (SNP) | VAF 209/467 reads (45%) | catalogued as rs1301458295, COSV64385684; called by muse, mutect2, varscan2
- CBLN3 | c.540T>A p.S180= | Silent (SNP) | VAF 30/638 reads (5%) | called by muse, mutect2
- FAM181B | c.1095C>T p.D365= | Silent (SNP) | VAF 356/741 reads (48%) | called by muse, mutect2, varscan2
- FBLN5 | c.192C>T p.G64= | Silent (SNP) | VAF 255/510 reads (50%) | catalogued as COSV50906868, COSV99969429; called by muse, mutect2, varscan2
- H2BE1 | c.294G>A p.L98= | Silent (SNP) | VAF 53/1007 reads (5%) | catalogued as rs578051087; called by muse, mutect2
- HAP1 | c.684G>A p.L228= | Silent (SNP) | VAF 10/264 reads (4%) | called by muse, mutect2
- IGHV2-5 | c.33G>C p.L11= | Silent (SNP) | VAF 24/369 reads (7%) | called by muse, mutect2
- ITGA11 | c.2463G>A p.T821= | Silent (SNP) | VAF 229/458 reads (50%) | catalogued as rs776462963, COSV59878584; called by muse, varscan2
- KHDRBS1 | c.219T>C p.G73= | Silent (SNP) | VAF 234/620 reads (38%) | called by muse, mutect2, varscan2
- PCDH19 | c.3024C>T p.C1008= (on ENST00000373034 / NM_001184880.2; = p.C960= on NM_020766.3) | Silent (SNP) | VAF 26/438 reads (6%) | catalogued as rs1266028176; ClinVar: likely benign; called by muse, mutect2
- PDCD7 | c.178C>T p.L60= | Silent (SNP) | VAF 367/742 reads (49%) | catalogued as rs1182651287; called by muse, mutect2, varscan2
- ZNF723 | c.963C>T p.A321= | Silent (SNP) | VAF 24/413 reads (6%) | called by muse, mutect2
- KCNQ1 | c.1394-9187C>T | Intron (SNP) | VAF 229/443 reads (52%) | catalogued as rs982026801; called by muse, mutect2, varscan2
